Somatic mutation profile of tumor specimen 0DTUXB from CCDI case PBCJAG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,649 days).
Specimen 0DTUXB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66384399-404b-4dba-bdca-516cfe74b6d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUX3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/207bb39f-dd4f-4d9a-acaa-b419b4f913ec

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MISP | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV53121691; called by muse, mutect2, varscan2
- MYH13 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 212/582 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1235110056; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 51/1809 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- PCCA | c.1644-1G>A p.X548_splice | Splice Site (SNP) | VAF 173/653 reads (26%) | called by muse, mutect2, varscan2
- TDRD6 | c.-10C>T | 5'UTR (SNP) | VAF 73/261 reads (28%) | catalogued as rs1396487357; called by muse, mutect2, varscan2
